Somatic mutation profile of tumor specimen TCGA-AA-3815-01A (aliquot TCGA-AA-3815-01A-01W-0995-10) from TCGA case TCGA-AA-3815, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.5 years (23,922 days).
Specimen TCGA-AA-3815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47228123-ca75-4806-9eba-139c53c6f6ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3815-10A (Blood Derived Normal), aliquot TCGA-AA-3815-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e77dc089-389e-46b6-9946-88d410bf43cd

The open-access MAF lists 1,049 somatic variants for this specimen: 808 protein-altering or splice-affecting, 227 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 572, Silent 227, Frame Shift Del 126, Frame Shift Ins 34, Nonsense Mutation 33, Splice Site 28, Intron 9, In Frame Del 8, Splice Region 7, 3'UTR 2, RNA 1, 5'Flank 1.

Variants (750 of 1,049; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 19/51 reads (37%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- APOA1 | c.85del p.Q29Rfs*7 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs753348565, CD961783; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BMPR2 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852746, CM002241, COSV65808187; ClinVar: pathogenic; called by muse, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DYSF | c.2810+1G>A p.X937_splice | Splice Site (SNP) | VAF 27/102 reads (26%) | catalogued as rs199954546, CS080679, COSV50326635; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- F5 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 61/341 reads (18%) | catalogued as rs757953549, CM980661, COSV100888970; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1634A>G p.Y545C (on ENST00000281708 / NM_001349798.2; = p.Y465C on NM_018315.5) | Missense Mutation (SNP) | VAF 122/291 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560758208, COSV55890892, COSV55908001, COSV55914345; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 63/175 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYL2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199474814, CM086878, COSV57406238; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 233/760 reads (31%) | catalogued as rs573607437; ClinVar: pathogenic; called by pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 44/154 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 73/304 reads (24%) | catalogued as rs786204934, CM110145, COSV64289396, COSV64297896; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 267/840 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 34/107 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USP9X | c.7440del p.A2481Pfs*7 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, pindel, varscan2
- A2ML1 | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 189/508 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV100228613; called by muse, mutect2, varscan2
- AADACL3 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 96/315 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100206582; called by muse, mutect2, varscan2
- ABCA13 | c.344T>A p.L115* | Nonsense Mutation (SNP) | VAF 52/209 reads (25%) | catalogued as rs1345447461, COSV101329950; called by muse, mutect2, varscan2
- ABCC2 | c.2556del p.G853Efs*7 | Frame Shift Del (DEL) | VAF 45/170 reads (26%) | catalogued as rs1393497113, COSV64984621, COSV64985681; called by mutect2, pindel, varscan2
- ABCF3 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760528913, COSV99491290; called by muse, mutect2, varscan2
- ABCF3 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 154/493 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99491294; called by muse, mutect2, varscan2
- ABCG4 | c.1220G>A p.G407D | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100266578; called by muse, mutect2, varscan2
- ABHD12 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs535070738, COSV100194252; called by muse, mutect2, varscan2
- ABHD13 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 26/530 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1183363120, COSV101024065; called by muse, mutect2
- ACHE | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs371841362, COSV99573838; called by muse, varscan2
- ACSF3 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as rs762286480, COSV58082598; called by muse, mutect2, varscan2
- ACTL6A | c.103-2A>G p.X35_splice | Splice Site (SNP) | VAF 59/183 reads (32%) | catalogued as COSV101199636; called by muse, mutect2, varscan2
- ACY3 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99662906; called by muse, mutect2, varscan2
- ADA2 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99375803; called by muse, mutect2, varscan2
- ADAM18 | c.828-2A>G p.X276_splice | Splice Site (SNP) | VAF 33/134 reads (25%) | catalogued as COSV99695054; called by muse, mutect2, varscan2
- ADAMTS1 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1173184694, COSV99535918; called by muse, mutect2, varscan2
- ADAMTS2 | c.3173C>T p.S1058L | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs767490706, COSV52368057; called by muse, mutect2, varscan2
- ADCY1 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52031540; called by muse, mutect2, varscan2
- ADGRD1 | c.567C>A p.S189R | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99894377; called by muse, mutect2, varscan2
- ADGRG4 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs745479559, COSV54957864; called by muse, mutect2
- AEBP1 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1244508507, COSV99788513; called by muse, mutect2, varscan2
- AFAP1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1371979218, COSV100631227; called by muse, mutect2
- AFF2 | c.2711C>A p.A904E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.425); catalogued as COSV53979204; called by muse, mutect2, varscan2
- AGT | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV100794234; called by muse, mutect2
- AHNAK | c.12676A>G p.I4226V | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs374783736; called by muse, mutect2
- AHNAK | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.106); catalogued as COSV99946074; called by muse, mutect2, varscan2
- ALG1 | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV99275488; called by mutect2, varscan2
- ALS2 | c.1815+2T>C p.X605_splice | Splice Site (SNP) | VAF 99/330 reads (30%) | catalogued as COSV99968905; called by muse, mutect2, varscan2
- ANKAR | c.3332T>G p.V1111G | Missense Mutation (SNP) | VAF 380/1177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55610182; called by muse, mutect2, varscan2
- ANKRD12 | c.5194C>A p.P1732T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV100040913, COSV50819304; called by muse, mutect2, varscan2
- ANKRD34B | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100103404; called by muse, mutect2, varscan2
- ANKRD39 | c.268T>C p.C90R | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV101135553; called by muse, varscan2
- ANO3 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs985723132, COSV99881231; called by muse, mutect2, varscan2
- API5 | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV66632636; called by muse, mutect2, varscan2
- APOBEC4 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 88/283 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs760123722, COSV100426080; called by muse, mutect2, varscan2
- APOH | c.885A>T p.K295N | Missense Mutation (SNP) | VAF 259/812 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as COSV99235606, COSV99235881; called by muse, mutect2, varscan2
- APP | c.473G>A p.C158Y | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771319862, COSV60994896; called by muse, mutect2, varscan2
- AR | c.91C>A p.R31S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.345); catalogued as COSV101017615, COSV101018342; called by muse, varscan2
- ARAP1 | c.3635T>C p.V1212A (on ENST00000393609 / NM_001040118.2; = p.V967A on NM_015242.4) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100501645; called by muse, mutect2, varscan2
- ARAP1 | c.959G>A p.G320E (on ENST00000393609 / NM_001040118.2; = p.G75E on NM_015242.4) | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.165); catalogued as rs1373002101, COSV100501647; called by muse, mutect2, varscan2
- AREL1 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 148/405 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.409); catalogued as rs1195685766, COSV100707578; called by muse, mutect2, varscan2
- ARHGAP32 | c.134T>C p.V45A | Missense Mutation (SNP) | VAF 222/729 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV100087148; called by muse, mutect2, varscan2
- ARHGAP36 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.068); catalogued as rs375987655, COSV99357359; called by muse, mutect2
- ARMCX1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100863162; called by muse, mutect2, varscan2
- ARMCX5 | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV55766895; called by muse, mutect2, varscan2
- ASB9 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100995396; called by muse, mutect2, varscan2
- ASTN2 | c.1753T>C p.S585P (on ENST00000313400 / NM_001365069.1; = p.S534P on NM_014010.5) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.755); catalogued as rs983782190, COSV100525318; called by muse, mutect2, varscan2
- ASXL2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs530632623, COSV55454257; called by muse, varscan2
- ASXL2 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 98/413 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99710445; called by muse, mutect2, varscan2
- ATAD3B | c.599G>A p.R200Q (on ENST00000308647; = p.R306Q on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs367992193; called by muse, mutect2, varscan2
- ATF7IP2 | c.1717A>G p.T573A | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV61092414; called by muse, mutect2, varscan2
- ATG9A | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV100772513; called by muse, mutect2, varscan2
- ATP10A | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV63514179; called by muse, mutect2, varscan2
- ATP10A | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs763246380, CM1513003, COSV63520922; called by muse, mutect2, varscan2
- ATP13A3 | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV55461973; called by muse, mutect2, varscan2
- ATXN2 | c.1841G>A p.R614H (on ENST00000550104; = p.R454H on NM_002973.4) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs751481895, COSV101112625; called by muse, mutect2, varscan2
- AXL | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV99996094; called by muse, mutect2, varscan2
- B4GALT4 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100785769; called by muse, mutect2, varscan2
- BABAM2 | c.1145A>G p.K382R | Missense Mutation (SNP) | VAF 111/346 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.678); catalogued as COSV100567443; called by muse, mutect2, varscan2
- BAG6 | c.2965del p.Q989Sfs*85 (on ENST00000676571; = p.Q942Sfs*85 on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 66/222 reads (30%) | catalogued as rs778695310; called by mutect2, pindel
- BANK1 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs751193940, COSV100535967; called by muse, mutect2, varscan2
- BARHL2 | c.218del p.P73Rfs*6 | Frame Shift Del (DEL) | VAF 18/33 reads (55%) | catalogued as COSV64981232; called by mutect2, varscan2
- BAZ1A | c.3535C>T p.R1179* | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as rs1324212960, COSV62412042; called by muse, mutect2, varscan2
- BAZ2B | c.4591A>G p.T1531A | Missense Mutation (SNP) | VAF 28/912 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as COSV100600439; called by muse, mutect2
- BBS2 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99802182; called by muse, mutect2, varscan2
- BCKDK | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV54890638; called by muse, mutect2, varscan2
- BEST4 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.213); catalogued as rs750519483, COSV64734634; called by muse, varscan2
- BGLAP | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs777313170, COSV99430770; called by muse, mutect2, varscan2
- BICD1 | c.2528A>C p.Q843P | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.374); catalogued as COSV55688063, COSV99862076; called by muse, mutect2, varscan2
- BICDL2 | c.1032dup p.K345Qfs*25 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | catalogued as rs769749885; called by mutect2, pindel
- BNC1 | c.199+2T>C p.X67_splice | Splice Site (SNP) | VAF 193/551 reads (35%) | catalogued as COSV100596962; called by muse, mutect2, varscan2
- BPTF | c.2230C>G p.Q744E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV100074311; called by muse, mutect2, varscan2
- BPTF | c.3259del p.I1087* | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | catalogued as rs757520968; called by mutect2, varscan2
- BSN | c.6785C>A p.P2262H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV99607562; called by muse, mutect2, varscan2
- BTBD9 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 120/443 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1050334109, COSV58421488; called by muse, mutect2, varscan2
- C1QB | c.628A>G p.M210V | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs943982832, COSV100152715; called by muse, mutect2, varscan2
- C1QTNF4 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs866041290, COSV100209144; called by muse, mutect2, varscan2
- C3 | c.2670dup p.K891Qfs*33 | Frame Shift Ins (INS) | VAF 22/53 reads (42%) | catalogued as rs750770711; called by mutect2, varscan2
- CAAP1 | c.571del p.I191Ffs*2 | Frame Shift Del (DEL) | VAF 60/168 reads (36%) | catalogued as rs754356646, COSV61700397; called by mutect2, varscan2
- CABP2 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1485571053, COSV99590750; called by muse, mutect2, varscan2
- CACNA1A | c.2384A>G p.E795G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV64191534; called by muse, mutect2, varscan2
- CACNA1F | c.4823A>G p.D1608G | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100544473; called by muse, mutect2, varscan2
- CACNA1H | c.441del p.F147Lfs*37 | Frame Shift Del (DEL) | VAF 30/101 reads (30%) | catalogued as rs868275022; called by mutect2, pindel, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | catalogued as rs745648688, COSV53168096; called by mutect2, varscan2
- CACNG7 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV99711879; called by muse, mutect2, varscan2
- CADPS | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 584/1832 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773569176, COSV99336458; called by muse, varscan2
- CAMK2G | c.1349+1G>A p.X450_splice (on ENST00000423381 / NM_001367518.1; = p.X387_splice on NM_001222.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 364/1037 reads (35%) | catalogued as COSV99989508; called by muse, varscan2
- CAMSAP2 | c.457A>G p.S153G | Missense Mutation (SNP) | VAF 174/456 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs1272814644, COSV99372971; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 31/110 reads (28%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAPZB | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99939662; called by muse, mutect2
- CARS2 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57284451; called by muse, mutect2, varscan2
- CC2D1A | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100528314; called by muse, mutect2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC27 | c.1915del p.L639Cfs*8 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs751021664; called by mutect2, pindel
- CCDC39 | c.1130T>A p.L377* | Nonsense Mutation (SNP) | VAF 22/488 reads (5%) | catalogued as COSV56480332, COSV99867661; called by muse, mutect2
- CCDC8 | c.960G>T p.R320S | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as COSV100281929; called by muse, mutect2, varscan2
- CCDC88B | c.2862+1G>T p.X954_splice | Splice Site (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100105132; called by muse, mutect2, varscan2
- CCDC9 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV99699564; called by muse, mutect2, varscan2
- CCNT1 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | catalogued as COSV99980529; called by muse, mutect2, varscan2
- CCRL2 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as COSV100644981; called by muse, mutect2, varscan2
- CD180 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV56518427; called by muse, mutect2, varscan2
- CD180 | c.501dup p.K168Qfs*16 | Frame Shift Ins (INS) | VAF 251/834 reads (30%) | catalogued as rs779093720; called by mutect2, pindel, varscan2
- CD1A | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 96/307 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs529984822, COSV99192234; called by muse, mutect2, varscan2
- CD200 | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV59862361; called by muse, mutect2, varscan2
- CD200R1L | c.241T>C p.Y81H | Missense Mutation (SNP) | VAF 63/826 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV101236555; called by muse, mutect2
- CDC23 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs761053901, COSV67509992; called by muse, mutect2, varscan2
- CDC34 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99296263; called by muse, mutect2, varscan2
- CDC73 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 209/631 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV66465313; called by muse, mutect2, varscan2
- CDH10 | c.189A>T p.L63F | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV100050431, COSV100053248; called by muse, mutect2, varscan2
- CDH4 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865878611, COSV64646292; called by muse, mutect2, varscan2
- CDHR5 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs760407741, COSV51564815; called by muse, mutect2, varscan2
- CDK12 | c.2168G>A p.C723Y | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101420383; called by muse, mutect2, varscan2
- CDK5RAP3 | c.836A>C p.E279A | Missense Mutation (SNP) | VAF 136/568 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV58114364; called by muse, varscan2
- CEACAM4 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 174/510 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs373281524; called by muse, mutect2, varscan2
- CENPI | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 51/1017 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs752225365, COSV54503737; called by muse, mutect2
- CEP120 | c.1907C>A p.P636H | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100070911; called by muse, mutect2, varscan2
- CFAP44 | c.2942T>C p.L981P | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV55609251; called by muse, mutect2, varscan2
- CFAP65 | c.3587T>C p.V1196A | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV100444769; called by muse, mutect2, varscan2
- CHCHD3 | c.251+2T>C p.X84_splice | Splice Site (SNP) | VAF 185/582 reads (32%) | catalogued as COSV52770650; called by muse, mutect2, varscan2
- CHD1 | c.2441T>C p.V814A | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99399169; called by muse, mutect2, varscan2
- CHD4 | c.5605C>G p.P1869A (on ENST00000357008 / NM_001363606.2; = p.P1879A on NM_001273.5) | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100445131, COSV58895983; called by muse, mutect2, varscan2
- CHD5 | c.976A>G p.R326G | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99312775; called by muse, mutect2, varscan2
- CHD7 | c.4040C>T p.A1347V | Missense Mutation (SNP) | VAF 120/313 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1434621688, COSV101418052; called by muse, mutect2, varscan2
- CHEK2 | c.1204G>A p.E402K (on ENST00000382580 / NM_001005735.2; = p.E359K on NM_007194.4) | Missense Mutation (SNP) | VAF 183/513 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100101218; called by muse, mutect2, varscan2
- CHST5 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358684012, COSV100291780; called by muse, mutect2, varscan2
- CHSY1 | c.666del p.P223Lfs*3 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs762321510; called by mutect2, varscan2
- CIAPIN1 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV101275866; called by muse, mutect2, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 55/207 reads (27%) | catalogued as rs749719822, COSV99752279; called by mutect2, pindel, varscan2
- CLCA2 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 21/328 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs778743042, COSV65287027; called by muse, mutect2
- CLEC1B | c.261A>T p.Q87H | Missense Mutation (SNP) | VAF 54/1242 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV100045982; called by muse, mutect2
- CLIP4 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 724/2007 reads (36%) | catalogued as COSV60749538; called by muse, mutect2, varscan2
- CLTCL1 | c.3932G>A p.R1311Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as rs374653579, COSV99594621; called by muse, mutect2, varscan2
- CNDP2 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV100158989; called by muse, mutect2, varscan2
- CNTNAP4 | c.2467A>T p.T823S | Missense Mutation (SNP) | VAF 281/955 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV56667850; called by muse, mutect2, varscan2
- COL4A2 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464563247, COSV64625507; called by muse, mutect2, varscan2
- COL5A3 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs138241329; called by muse, mutect2, varscan2
- COL7A1 | c.7794G>A p.P2598= | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as rs377067446, COSV99866033; called by muse, mutect2
- COMMD2 | c.387G>T p.W129C | Missense Mutation (SNP) | VAF 171/540 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101511894, COSV71946538; called by muse, mutect2
- COX6B2 | c.73A>G p.S25G | Missense Mutation (SNP) | VAF 165/483 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100427703; called by muse, mutect2, varscan2
- CPNE8 | c.1144-2A>G p.X382_splice | Splice Site (SNP) | VAF 111/323 reads (34%) | catalogued as COSV58839113; called by muse, mutect2, varscan2
- CPNE9 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 87/296 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs755372206, COSV56067816; called by muse, mutect2, varscan2
- CPSF1 | c.1717G>T p.G573* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100574269, COSV62938822; called by muse, mutect2
- CPT1A | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 129/2268 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1425369664, COSV99680741; called by muse, mutect2
- CRAT | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100539869; called by muse, mutect2
- CREBBP | c.4813A>G p.K1605E | Missense Mutation (SNP) | VAF 363/1504 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99268931; called by muse, mutect2, varscan2
- CRLF3 | c.343A>G p.I115V | Missense Mutation (SNP) | VAF 235/817 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60835271; called by muse, mutect2, varscan2
- CRYZ | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 19/381 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV61717097; called by muse, mutect2
- CSMD1 | c.3008C>T p.S1003L (on ENST00000520002; = p.S1002L on NM_033225.6) | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59334988; called by muse, mutect2, varscan2
- CSMD2 | c.9584C>T p.T3195M | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs180811686; called by muse, mutect2, varscan2
- CSNK1G3 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 21/670 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV62054390; called by muse, mutect2
- CSTF2T | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100484101; called by muse, mutect2, varscan2
- CTNND2 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 61/229 reads (27%) | catalogued as COSV100473060; called by muse, mutect2, varscan2
- CUL1 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.044); catalogued as COSV100296489; called by muse, mutect2, varscan2
- CUL7 | c.4690C>T p.R1564W | Missense Mutation (SNP) | VAF 149/489 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761970375, COSV54821324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CWF19L1 | c.619T>C p.Y207H | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs906443047, COSV100821469; called by muse, mutect2, varscan2
- CYP11B2 | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549871929, COSV59998253; called by muse, mutect2
- CYP2S1 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100027365; called by muse, varscan2
- DAPK3 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs547931912, COSV56662098; called by muse, mutect2, varscan2
- DCAF6 | c.880_882del p.S294del | In Frame Del (DEL) | VAF 46/160 reads (29%) | catalogued as rs1236795211; called by mutect2, pindel, varscan2
- DCAF7 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 70/217 reads (32%) | catalogued as COSV100177575; called by muse, mutect2, varscan2
- DCANP1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.202); catalogued as rs377125441; called by muse, mutect2, varscan2
- DGKH | c.3502T>C p.Y1168H | Missense Mutation (SNP) | VAF 216/662 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324994245, COSV54933207, COSV54938809; called by muse, mutect2, varscan2
- DIAPH2 | c.1262C>A p.A421D | Missense Mutation (SNP) | VAF 83/274 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100231432; called by muse, mutect2, varscan2
- DLG5 | c.4069T>C p.S1357P | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100967307; called by muse, mutect2, varscan2
- DNAAF4 | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 126/509 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58246962; called by muse, mutect2, varscan2
- DNAH11 | c.3574C>T p.P1192S | Missense Mutation (SNP) | VAF 95/356 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100177830; called by muse, mutect2, varscan2
- DNAH11 | c.7630T>C p.S2544P | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100177835; called by muse, mutect2, varscan2
- DNAJA4 | c.844G>A p.D282N (on ENST00000343789; = p.D311N on NM_018602.3) | Missense Mutation (SNP) | VAF 163/476 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100655141; called by muse, mutect2, varscan2
- DNAJC3 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV65130653; called by muse, mutect2
- DOCK8 | c.2855del p.P952Qfs*24 | Frame Shift Del (DEL) | VAF 24/85 reads (28%) | catalogued as COSV101210042; called by mutect2, pindel, varscan2
- DPP10 | c.444T>C p.I148= | Splice Region (SNP) | VAF 90/284 reads (32%) | catalogued as COSV59668474, COSV59738388; called by muse, varscan2
- DPP3 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766673185, COSV64758348; called by muse, mutect2, varscan2
- DSCAM | c.2657del p.P886Qfs*57 | Frame Shift Del (DEL) | VAF 351/1762 reads (20%) | catalogued as COSV101260464; called by pindel, varscan2
- DSCAML1 | c.388G>A p.V130M (on ENST00000321322; = p.V70M on NM_020693.4) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393957887, COSV58382031; called by muse, mutect2, varscan2
- DSP | c.4373G>A p.R1458Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs370063434, COSV65791413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.5888A>G p.K1963R | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV99245020; called by muse, mutect2, varscan2
- ECM2 | c.1235T>A p.L412* | Nonsense Mutation (SNP) | VAF 446/1429 reads (31%) | catalogued as COSV60739295, COSV60743461; called by muse, mutect2, varscan2
- ECT2 | c.486+2T>C p.X162_splice (on ENST00000392692 / NM_001349098.2; = p.X131_splice on NM_018098.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 38/723 reads (5%) | catalogued as COSV99221016; called by muse, mutect2
- EGLN1 | c.827T>C p.M276T | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100791216; called by muse, mutect2, varscan2
- EID3 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.851); catalogued as COSV100723342; called by muse, mutect2, varscan2
- EIF3A | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs542911129; called by muse, varscan2
- EMC4 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 310/961 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.023); catalogued as COSV99970820; called by mutect2, varscan2
- ENAM | c.209A>G p.H70R | Missense Mutation (SNP) | VAF 275/1563 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.931); catalogued as COSV101252959; called by muse, mutect2, varscan2
- ENG | c.189A>C p.E63D | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100785242; called by muse, mutect2, varscan2
- ENGASE | c.392T>C p.M131T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100285679; called by muse, mutect2, varscan2
- EPB41L3 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs1469881115, COSV100548303; called by muse, varscan2
- EPB41L4B | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs532088774, COSV101000867; called by muse, mutect2, varscan2
- EPG5 | c.4018T>A p.F1340I | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99956681; called by muse, mutect2, varscan2
- EPHA4 | c.1507C>A p.L503M | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56027841; called by muse, mutect2, varscan2
- EPHA7 | c.992C>A p.P331H | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100993374; called by muse, mutect2, varscan2
- EPHB3 | c.1759C>T p.H587Y | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV100382856; called by muse, mutect2, varscan2
- ERBB4 | c.2843A>T p.D948V | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100723875; called by muse, mutect2, varscan2
- ERBB4 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV53576494; called by muse, mutect2, varscan2
- ERCC3 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV99573123; called by muse, mutect2, varscan2
- ESRP2 | c.2143C>T p.R715C (on ENST00000565858 / NM_001365264.1; = p.R705C on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs569178519, COSV99251148; called by muse, mutect2, varscan2
- ETV5 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV60500096; called by muse, mutect2, varscan2
- FAAH2 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 191/542 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV100887184; called by muse, mutect2, varscan2
- FAM135B | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as rs778940068, COSV50531836; called by muse, mutect2, varscan2
- FAM155B | c.554del p.N185Tfs*40 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | catalogued as rs749254240; called by mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM76B | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 195/532 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs934415639, COSV62557427; called by muse, mutect2, varscan2
- FAM91A1 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs754338365, COSV100593440, COSV58235865; called by muse, mutect2, varscan2
- FAM9A | c.79del p.A27Pfs*70 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as COSV101121339; called by mutect2, pindel, varscan2
- FASLG | c.422del p.K141Rfs*3 | Frame Shift Del (DEL) | VAF 94/331 reads (28%) | catalogued as rs35774809; called by mutect2, pindel, varscan2
- FAT4 | c.7922T>A p.I2641K | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100627522; called by muse, mutect2, varscan2
- FAT4 | c.12878A>T p.E4293V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100627525; called by muse, mutect2, varscan2
- FATE1 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774947821, COSV100948118; called by muse, mutect2, varscan2
- FBXL14 | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100201424; called by muse, mutect2, varscan2
- FBXO11 | c.712C>T p.Q238* (on ENST00000403359 / NM_001190274.2; = p.Q154* on NM_025133.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV57020333; called by muse, mutect2, varscan2
- FBXO9 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 87/266 reads (33%) | catalogued as rs989988566, COSV99762286; called by muse, mutect2, varscan2
- FDPS | c.395T>A p.V132E | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.084); catalogued as COSV100756111; called by muse, mutect2, varscan2
- FEZ1 | c.655T>C p.W219R | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.77); catalogued as rs745432120, COSV99630344; called by muse, mutect2, varscan2
- FGD3 | c.1288G>A p.V430I | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs778590186, COSV61595838; called by muse, mutect2, varscan2
- FHDC1 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV52598110; called by muse, mutect2, varscan2
- FHL5 | c.31T>C p.C11R | Missense Mutation (SNP) | VAF 166/578 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100459215; called by muse, mutect2, varscan2
- FLOT1 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as rs1243922743, COSV100899808; called by muse, mutect2, varscan2
- FMO3 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 170/554 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs754517205, COSV100882409; called by muse, mutect2, varscan2
- FMO4 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs573059844, COSV100882034; called by muse, mutect2, varscan2
- FRA10AC1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63271130; called by muse, mutect2, varscan2
- FRYL | c.5260A>G p.M1754V | Missense Mutation (SNP) | VAF 160/442 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99976146; called by muse, varscan2
- FTMT | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV58419719, COSV58421012; called by muse, mutect2
- GABRA2 | c.1142A>C p.D381A | Missense Mutation (SNP) | VAF 181/597 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as COSV100733933; called by muse, mutect2, varscan2
- GAL3ST4 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99444410; called by muse, mutect2, varscan2
- GALNT17 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as rs539625010, COSV100352719; called by muse, mutect2, varscan2
- GAPVD1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.921); catalogued as rs781673298, COSV99782782; called by muse, mutect2, varscan2
- GBE1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV70097344; called by muse, mutect2, varscan2
- GDF11 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV57689334; called by muse, mutect2
- GDF3 | c.1088G>A p.C363Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100325143; called by muse, varscan2
- GFM1 | c.367+2T>C p.X123_splice | Splice Site (SNP) | VAF 15/266 reads (6%) | catalogued as COSV99962751; called by muse, mutect2
- GIMAP8 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as rs758582699, COSV100217370, COSV56231132; called by muse, mutect2
- GK2 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 188/539 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100725869, COSV62626389; called by muse, mutect2, varscan2
- GLB1 | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 22/580 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100257155, COSV56563982; called by muse, mutect2
- GLT6D1 | c.182T>C p.F61S | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100874507; called by muse, mutect2, varscan2
- GOLGA3 | c.2375T>C p.L792P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs745663867, COSV99202327; called by muse, mutect2, varscan2
- GPAT3 | c.950A>G p.K317R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100023054, COSV52355789; called by muse, mutect2, varscan2
- GPR137B | c.895T>A p.F299I | Missense Mutation (SNP) | VAF 88/3304 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1232161672, COSV100858329; called by muse, mutect2
- GPR162 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.153); catalogued as COSV50589311; called by muse, mutect2, varscan2
- GRAMD1C | c.1702T>A p.L568I | Missense Mutation (SNP) | VAF 87/1840 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100822798; called by muse, mutect2
- GRHL2 | c.1385_1387del p.K462del | In Frame Del (DEL) | VAF 44/160 reads (28%) | catalogued as rs1429229736; called by pindel, varscan2
- GRIK1 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769701953, COSV58731117; called by muse, mutect2, varscan2
- GRIK5 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99490170; called by muse, mutect2, varscan2
- GUF1 | c.1692G>T p.E564D | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV55784409, COSV99877110; called by muse, mutect2, varscan2
- HCFC1 | c.4631C>T p.P1544L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.019); catalogued as rs1557113017, COSV60069876; called by muse, mutect2, varscan2
- HCN4 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 229/603 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370442588, COSV99983260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 87/302 reads (29%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel, varscan2
- HDAC4 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs373617636; called by muse, mutect2, varscan2
- HEXA | c.672+2T>C p.X224_splice | Splice Site (SNP) | VAF 60/189 reads (32%) | catalogued as COSV99173687; called by muse, mutect2, varscan2
- HJURP | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 52/200 reads (26%) | catalogued as rs765753648, COSV64978448; called by muse, mutect2, varscan2
- HLA-DOA | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs771856453, COSV100008122; called by muse, mutect2, varscan2
- HLA-DRB1 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.974); catalogued as COSV100750961, COSV63512576; called by muse, varscan2
- HLA-G | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV100827004; called by muse, mutect2, varscan2
- HLCS | c.1479G>T p.M493I | Missense Mutation (SNP) | VAF 77/235 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV100357946; called by muse, mutect2, varscan2
- HLCS | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV100357949; called by muse, mutect2
- HNRNPH1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV61485039; called by muse, mutect2, varscan2
- HOXB1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs751611344, COSV53318365; called by muse, mutect2, varscan2
- HPSE2 | c.57del p.A20Rfs*3 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as COSV65189625; called by mutect2, pindel
- HS3ST2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54465551; called by muse, mutect2, varscan2
- HSD17B2 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99556478; called by muse, mutect2, varscan2
- HSP90B1 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 175/522 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368374645; called by muse, mutect2, varscan2
- HYKK | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 274/1182 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.124); catalogued as COSV101195010; called by muse, mutect2, varscan2
- IBTK | c.2379T>G p.Y793* | Nonsense Mutation (SNP) | VAF 58/167 reads (35%) | catalogued as COSV100090170; called by muse, mutect2, varscan2
- ICE1 | c.6502T>C p.S2168P | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV56820214; called by muse, mutect2, varscan2
- IFFO1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 201/478 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758037048, COSV100350882; called by muse, mutect2, varscan2
- IGFBP7 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs146423345, COSV55271788; called by muse, mutect2, varscan2
- IGSF22 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1406491253, COSV60031545; called by muse, mutect2
- IL16 | c.367A>T p.S123C | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.436); catalogued as COSV57261076; called by muse, mutect2, varscan2
- IL18R1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764548979, COSV99294915; called by muse, mutect2, varscan2
- INAVA | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV66256019; called by muse, mutect2, varscan2
- INPP5B | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs777627979, COSV100886095; called by muse, mutect2, varscan2
- INPP5D | c.2369T>C p.I790T (on ENST00000445964 / NM_001017915.3; = p.I789T on NM_005541.5) | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64035735; called by muse, mutect2, varscan2
- INPPL1 | c.861G>T p.Q287H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV99995952; called by muse, mutect2, varscan2
- INTS8 | c.837del p.F279Lfs*6 | Frame Shift Del (DEL) | VAF 54/196 reads (28%) | catalogued as COSV58249114; called by mutect2, pindel, varscan2
- IPMK | c.956C>G p.A319G | Missense Mutation (SNP) | VAF 156/503 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100880242; called by muse, mutect2, varscan2
- IPO13 | c.1258T>C p.F420L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.786); catalogued as COSV100961068; called by muse, mutect2
- IQSEC1 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs773493024, COSV56220789; called by muse, mutect2, varscan2
- IRX4 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373640113, COSV51474859; called by muse, mutect2, varscan2
- ITGAX | c.2167G>A p.V723M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1265999102, COSV99191509; called by muse, mutect2, varscan2
- ITGB1BP2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs376544356, COSV99338646; called by muse, mutect2, varscan2
- ITIH2 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 172/926 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs766693296, COSV64432348; called by muse, mutect2, varscan2
- ITIH6 | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs781390419, COSV54488448; called by muse, mutect2, varscan2
- ITPA | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 464/1478 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs777033296, COSV66318319; called by muse, mutect2, varscan2
- ITPR1 | c.2416C>T p.R806C (on ENST00000354582; = p.R791C on NM_002222.7) | Missense Mutation (SNP) | VAF 67/114 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100230020; called by muse, mutect2, varscan2
- JAK2 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV101071050; called by muse, mutect2, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 190/759 reads (25%) | catalogued as rs763250381; called by mutect2, pindel, varscan2
- JKAMP | c.529T>C p.F177L (on ENST00000554271 / NM_001284201.1; = p.F163L on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/914 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.391); catalogued as COSV99711420; called by muse, mutect2, varscan2
- KAT14 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100890042; called by muse, mutect2, varscan2
- KBTBD6 | c.1789A>G p.N597D | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.26); catalogued as rs1374881281, COSV101068722; called by muse, mutect2
- KCNH1 | c.2603C>T p.A868V (on ENST00000271751 / NM_172362.3; = p.A841V on NM_002238.4) | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs773735492, COSV55091075; called by muse, mutect2, varscan2
- KCNIP4 | c.188T>A p.M63K | Missense Mutation (SNP) | VAF 28/510 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV62846161; called by muse, mutect2
- KDM2B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs782033254, COSV65638501; called by muse, mutect2, varscan2
- KIAA0586 | c.2856T>A p.S952R (on ENST00000619416 / NM_001244190.2; = p.S891R on NM_014749.5) | Missense Mutation (SNP) | VAF 256/863 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54172011; called by muse, varscan2
- KIAA1586 | c.128T>A p.L43H | Missense Mutation (SNP) | VAF 332/1185 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100875301; called by muse, mutect2, varscan2
- KIDINS220 | c.2711A>G p.Y904C | Missense Mutation (SNP) | VAF 114/389 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV99875181; called by muse, mutect2, varscan2
- KIF16B | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 208/552 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.063); catalogued as rs144734414; called by muse, mutect2, varscan2
- KIF21A | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100735348; called by muse, mutect2, varscan2
- KIF22 | c.1796G>A p.G599D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1395764185, COSV99360914; called by muse, mutect2
- KIF6 | c.991-1G>T p.X331_splice | Splice Site (SNP) | VAF 78/308 reads (25%) | catalogued as COSV54668893; called by muse, mutect2, varscan2
- KIFAP3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100846784; called by muse, mutect2, varscan2
- KL | c.2461C>G p.P821A | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV101199033; called by muse, mutect2, varscan2
- KLB | c.1588A>G p.T530A | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.306); catalogued as COSV99962000; called by muse, mutect2, varscan2
- KNSTRN | c.74A>G p.H25R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51103747; called by muse, mutect2, varscan2
- KRTAP4-4 | c.217C>G p.P73A | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV66811230; called by muse, mutect2, varscan2
- LAMB4 | c.4517T>G p.V1506G | Missense Mutation (SNP) | VAF 169/607 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99223168; called by muse, mutect2, varscan2
- LARGE1 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.153); catalogued as rs140257955; called by muse, mutect2, varscan2
- LCA5 | c.1006A>G p.M336V | Missense Mutation (SNP) | VAF 146/1222 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100878189; called by muse, varscan2
- LCE1E | c.232A>C p.S78R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV100908517; called by muse, mutect2, varscan2
- LEF1 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 126/501 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as COSV99489357; called by muse, mutect2, varscan2
- LETM2 | c.501G>T p.R167S (on ENST00000379957 / NM_001286819.2; = p.R120S on NM_144652.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99907306; called by muse, mutect2
- LIMCH1 | c.122A>T p.D41V | Missense Mutation (SNP) | VAF 202/722 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100573508; called by muse, mutect2, varscan2
- LIN54 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 137/427 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); catalogued as rs1166739721, COSV100464305; called by muse, mutect2, varscan2
- LONP1 | c.1688G>A p.R563Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100638547; called by muse, mutect2, varscan2
- LRFN2 | c.1325T>C p.V442A | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV100599198; called by muse, mutect2, varscan2
- LRRC2 | c.1068A>T p.E356D | Missense Mutation (SNP) | VAF 105/353 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV56125186; called by muse, mutect2, varscan2
- LRRC31 | c.731A>T p.N244I | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV99246405; called by muse, mutect2, varscan2
- LRRC59 | c.443T>C p.M148T | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV99869415; called by muse, mutect2, varscan2
- LRRIQ1 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101277698; called by muse, mutect2
- LRRN2 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs139192228; called by muse, mutect2, varscan2
- LSS | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs750622768, COSV100710829; called by muse, varscan2
- LTBP4 | c.4224del p.A1409Hfs*20 (on ENST00000308370 / NM_001042544.1; = p.A1372Hfs*20 on NM_003573.2) | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs754757253, COSV52588935; called by mutect2, varscan2
- LUC7L | c.71C>A p.T24N | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as rs1286748852, COSV99551027; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1306690163, COSV65442592; called by muse, mutect2
- LZTR1 | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV99301420; called by muse, mutect2, varscan2
- MACF1 | c.9791T>C p.V3264A | Missense Mutation (SNP) | VAF 81/350 reads (23%) | catalogued as rs373244652; called by muse, mutect2, varscan2
- MALT1 | c.608G>A p.W203* | Nonsense Mutation (SNP) | VAF 170/645 reads (26%) | catalogued as COSV61934211; called by muse, mutect2, varscan2
- MANEAL | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100203847; called by muse, mutect2, varscan2
- MAP2K1 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1013906172, COSV61073359; called by muse, mutect2, varscan2
- MAP4 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1168853278, COSV99274842; called by muse, mutect2, varscan2
- MAP4 | c.1901A>G p.K634R | Missense Mutation (SNP) | VAF 30/572 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV99274844; called by muse, mutect2
- MAPT | c.2272G>A p.G758R (on ENST00000262410 / NM_001377265.1; = p.G366R on NM_005910.5) | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs948573449, CM121237, COSV52240278; called by muse, mutect2, varscan2
- MAST1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377652181, COSV52240739; called by muse, mutect2, varscan2
- MAST3 | c.1664A>C p.Q555P | Missense Mutation (SNP) | VAF 154/487 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99444630; called by muse, mutect2, varscan2
- MCC | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV101342714; called by muse, mutect2
- MDM1 | c.1971T>C p.N657= | Splice Region (SNP) | VAF 90/248 reads (36%) | catalogued as COSV100291664; called by muse, mutect2, varscan2
- MDM4 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs910719305; called by muse, varscan2
- MED13L | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 266/796 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV99928063; called by muse, mutect2, varscan2
- MED15 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV53027225; called by muse, mutect2, varscan2
- MEGF8 | c.3007T>C p.C1003R (on ENST00000251268 / NM_001271938.2; = p.C936R on NM_001410.3) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52077017; called by muse, mutect2, varscan2
- MEGF8 | c.5731G>A p.G1911R (on ENST00000251268 / NM_001271938.2; = p.G1844R on NM_001410.3) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs574708619, COSV52077024; called by muse, mutect2, varscan2
- METTL3 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV99398057; called by muse, mutect2, varscan2
- MFAP3L | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 291/852 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759625030, COSV64371714; called by muse, mutect2, varscan2
- MFSD6L | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100266211; called by muse, mutect2, varscan2
- MGAT1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | PolyPhen benign (0.106); catalogued as COSV100286547; called by muse, mutect2, varscan2
- MIA | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs371769033; called by muse, mutect2, varscan2
- MIGA2 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs549699802, COSV52978461; called by muse, mutect2, varscan2
- MKI67 | c.8672G>A p.R2891Q | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs534128566, COSV100896270, COSV100896353; called by muse, mutect2, varscan2
- MMP19 | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100490999; called by muse, mutect2
- MMUT | c.2127T>A p.D709E | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99222206; called by muse, mutect2, varscan2
- MOSPD3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); catalogued as rs761672945, COSV56158512, COSV99774894; called by muse, mutect2, varscan2
- MPEG1 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.335); catalogued as COSV57088791; called by muse, mutect2, varscan2
- MRGPRX3 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.955); catalogued as rs750509886, COSV101283503, COSV66933793; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 83/266 reads (31%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MROH5 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs200930548; called by muse, mutect2, varscan2
- MRPL39 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs747586864, COSV100220870; called by muse, mutect2, varscan2
- MRPS9 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99305915; called by muse, mutect2
- MX2 | c.249+2T>C p.X83_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100415787; called by muse, mutect2, varscan2
- MYH13 | c.1825G>T p.G609W | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52822131; called by muse, mutect2
- MYH2 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs778709891, COSV55431152; called by muse, mutect2, varscan2
- MYH4 | c.3086C>T p.T1029I | Missense Mutation (SNP) | VAF 86/382 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99700547; called by muse, mutect2, varscan2
- MYH6 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 215/589 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs751285148, COSV62451058; called by muse, mutect2, varscan2
- MYH7 | c.3302G>A p.G1101D | Missense Mutation (SNP) | VAF 126/334 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.099); catalogued as COSV100805786; called by muse, mutect2, varscan2
- MYH7B | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs1455974261, COSV99482429; called by muse, mutect2, varscan2
- MYLK | c.2657C>T p.A886V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs140989388, COSV60612823; called by muse, mutect2, varscan2
- MYLK4 | c.75dup p.Q26Sfs*27 | Frame Shift Ins (INS) | VAF 288/967 reads (30%) | catalogued as rs762913642; called by mutect2, pindel, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 45/134 reads (34%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO1E | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 107/299 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs757483863, COSV55686356; called by muse, mutect2, varscan2
- MYO7B | c.3027C>T p.A1009= | Splice Region (SNP) | VAF 14/42 reads (33%) | catalogued as rs202235279, COSV67345147; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- MZT2A | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.954); catalogued as COSV100342393; called by muse, mutect2
- NACC1 | c.1057A>C p.N353H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.851); catalogued as COSV99456820; called by muse, mutect2, varscan2
- NARF | c.414A>G p.I138M | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV59110784; called by muse, mutect2, varscan2
- NASP | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 163/535 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs747014903, COSV63111724; called by muse, mutect2, varscan2
- NCK2 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs766993432, COSV99255357; called by muse, mutect2, varscan2
- NCOA2 | c.4381C>T p.R1461W | Missense Mutation (SNP) | VAF 111/415 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV51221274; called by muse, mutect2, varscan2
- NCOR2 | c.6219G>T p.E2073D | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as COSV62294191; called by muse, mutect2, varscan2
- NELL1 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 104/376 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs375631199, COSV99040633; called by muse, mutect2, varscan2
- NF2 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 4/65 reads (6%) | catalogued as rs1341371726; called by muse, mutect2
- NFAT5 | c.1142+1G>A p.X381_splice | Splice Site (SNP) | VAF 22/72 reads (31%) | catalogued as COSV63025519; called by muse, mutect2, varscan2
- NFRKB | c.1507C>T p.R503W (on ENST00000446488 / NM_001143835.2; = p.R528W on NM_006165.3) | Missense Mutation (SNP) | VAF 119/370 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs764142634, COSV100451810; called by muse, mutect2, varscan2
- NFRKB | c.70C>T p.R24C (on ENST00000446488 / NM_001143835.2; = p.R37C on NM_006165.3) | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs556684595, COSV58756237; called by muse, mutect2, varscan2
- NKTR | c.1481A>G p.H494R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99235332; called by muse, mutect2, varscan2
- NLRP1 | c.4279C>T p.R1427W (on ENST00000572272 / NM_033004.4; = p.R1383W on NM_014922.5) | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754014640, COSV52566950, COSV99335467; called by muse, mutect2, varscan2
- NLRX1 | c.428del p.P143Hfs*81 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | catalogued as rs767102699; called by mutect2, pindel, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 34/81 reads (42%) | catalogued as rs751187638; called by mutect2, varscan2
- NOS1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs374847966; called by muse, mutect2, varscan2
- NPHP4 | c.1934T>C p.L645P | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100976754; called by muse, mutect2, varscan2
- NPY5R | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 35/432 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs143395004, COSV100642674; called by muse, mutect2
- NRDC | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV61405422; called by muse, mutect2, varscan2
- NSD1 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as rs1460977537, COSV100728559; called by muse, mutect2, varscan2
- NTRK3 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100445912; called by muse, mutect2, varscan2
- NUB1 | c.990del p.K330Nfs*2 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | catalogued as rs760102115; called by mutect2, varscan2
- NUDT13 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV61968016; called by muse, mutect2
- NUMA1 | c.5021G>A p.R1674H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs748328523, COSV59644089; called by muse, mutect2
- NUP107 | c.1790C>G p.P597R | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99971567; called by muse, mutect2, varscan2
- NUP35 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99717744; called by muse, varscan2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 42/121 reads (35%) | catalogued as rs781171419; called by mutect2, varscan2
- OBSCN | c.9697C>T p.R3233C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs367605500; called by muse, mutect2, varscan2
- OCM | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 168/560 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772780728, COSV54194176; called by muse, mutect2, varscan2
- OGT | c.2288A>G p.D763G | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.021); catalogued as COSV101035221; called by muse, mutect2, varscan2
- OR10Z1 | c.265del p.D89Tfs*48 | Frame Shift Del (DEL) | VAF 139/530 reads (26%) | catalogued as rs752054889; called by mutect2, pindel, varscan2
- OR13C5 | c.945T>A p.N315K | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs772763047, COSV66164315; called by muse, mutect2, varscan2
- OR14J1 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 183/578 reads (32%) | catalogued as COSV65845533; called by muse, mutect2, varscan2
- OR2L2 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100823262; called by muse, mutect2, varscan2
- OR2M2 | c.926A>T p.K309M | Missense Mutation (SNP) | VAF 146/474 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV62897925, COSV62898897; called by muse, mutect2, varscan2
- OR51B4 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV100970821; called by muse, mutect2, varscan2
- OR51T1 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 132/389 reads (34%) | catalogued as rs775048791, COSV100434319; called by muse, mutect2, varscan2
- OR56A3 | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100290031, COSV100290123; called by muse, mutect2, varscan2
- OR5B12 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 52/197 reads (26%) | catalogued as rs142424894, COSV56906644, COSV56906748; called by muse, mutect2, varscan2
- OR5I1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1444518955, COSV100041221; called by muse, mutect2, varscan2
- OR8H3 | c.167T>A p.L56H | Missense Mutation (SNP) | VAF 134/461 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100538791, COSV57908101, COSV57910433; called by muse, mutect2, varscan2
- OSM | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs535625269, COSV53160852; called by muse, mutect2, varscan2
- OTOF | c.3910G>A p.E1304K (on ENST00000272371 / NM_194248.3; = p.E537K on NM_004802.4) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1414447103, COSV55497209; called by muse, mutect2, varscan2
- P2RX4 | c.895T>C p.Y299H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.399); catalogued as COSV100464931; called by muse, mutect2
- PAK5 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 154/427 reads (36%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.017); catalogued as COSV100781178, COSV99058916; called by muse, mutect2, varscan2
- PANK3 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53322040; called by muse, mutect2, varscan2
- PAPPA | c.2911T>C p.C971R | Missense Mutation (SNP) | VAF 280/821 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100073145; called by muse, mutect2, varscan2
- PAPPA | c.3259C>T p.R1087W | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs762183020, COSV100073148; called by muse, mutect2, varscan2
- PAX8 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99639225; called by muse, mutect2, varscan2
- PCDH9 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60526324; called by muse, mutect2, varscan2
- PCDH9 | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.326); catalogued as rs1377781576, COSV100118974; called by muse, mutect2, varscan2
- PCDHA6 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs1184044703, COSV100971286, COSV65344461; called by muse, mutect2, varscan2
- PCDHB12 | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99506900; called by muse, mutect2, varscan2
- PCDHB5 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as COSV99167694; called by muse, mutect2, varscan2
- PCDHGA1 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs1415948190, COSV100965922, COSV65295220; called by muse, mutect2, varscan2
- PCDHGB6 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.904); catalogued as rs764101918, COSV53909069; called by muse, mutect2, varscan2
- PCGF2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 23/460 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs968126661; called by muse, mutect2
- PCLO | c.2644C>T p.R882* | Nonsense Mutation (SNP) | VAF 314/1066 reads (29%) | catalogued as COSV61619487; called by muse, mutect2, varscan2
- PCP2 | c.16_18del p.E6del | In Frame Del (DEL) | VAF 28/161 reads (17%) | catalogued as rs976485849; called by pindel, varscan2
- PDE4B | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 117/346 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV100302577; called by muse, mutect2, varscan2
- PDE5A | c.2375G>C p.R792T | Missense Mutation (SNP) | VAF 428/1108 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV99308407; called by muse, varscan2
- PDE6A | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99677941; called by muse, mutect2, varscan2
- PDGFRB | c.2783A>G p.H928R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1360746335, COSV99940276; called by muse, mutect2, varscan2
- PDILT | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100199153; called by muse, mutect2, varscan2
- PDZD4 | c.2122G>T p.E708* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99381121; called by muse, mutect2, varscan2
- PELP1 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52586181; called by muse, mutect2, varscan2
- PGLYRP1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99151487; called by muse, mutect2, varscan2
- PKN3 | c.2473G>T p.A825S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV52575211; called by muse, mutect2, varscan2
- PLAAT3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.21); catalogued as rs1037394961, COSV100071686; called by muse, mutect2, varscan2
- PLCB4 | c.1762A>G p.I588V | Missense Mutation (SNP) | VAF 51/1168 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99594629; called by muse, mutect2
- PLEK | c.718_720del p.E240del | In Frame Del (DEL) | VAF 150/610 reads (25%) | catalogued as rs1336183164; called by pindel, varscan2
- PLP1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 90/340 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as CD084184, COSV100393300, COSV100393323; called by muse, mutect2, varscan2
- PLP2 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 153/566 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782368813, COSV100890104; called by muse, mutect2, varscan2
- PLXNB1 | c.2892G>T p.E964D | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1482048510, COSV99602443; called by muse, mutect2, varscan2
- PNMA3 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as rs782587383, COSV64722470; called by muse, mutect2, varscan2
- POLB | c.951del p.D318Tfs*42 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as rs780460727; called by mutect2, pindel, varscan2
- POLE | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs765254190, COSV57675269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR1B | c.3107G>A p.R1036H | Missense Mutation (SNP) | VAF 112/1572 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54496704; called by muse, mutect2
- POLR3C | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 21/73 reads (29%) | catalogued as rs782450329, COSV61937002; called by muse, mutect2, varscan2
- POM121L12 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV101374855; called by muse, mutect2, varscan2
- POP1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 292/951 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs781072902, COSV62892312, COSV62893554; called by muse, mutect2, varscan2
- POP5 | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs1348328239, COSV58043849; called by muse, mutect2, varscan2
- PPEF1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 144/436 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs374360016, COSV62996254; called by muse, mutect2, varscan2
- PPFIA2 | c.2785G>T p.A929S | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100332056; called by muse, mutect2, varscan2
- PPP3CB | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs149808527, COSV61150802; called by muse, mutect2, varscan2
- PRDM4 | c.1653G>T p.K551N | Missense Mutation (SNP) | VAF 196/553 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99946420; called by muse, mutect2, varscan2
- PREPL | c.1509A>G p.I503M | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs1480510100, COSV53215391; called by muse, mutect2, varscan2
- PREX1 | c.3805C>T p.R1269C | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs1045054984, COSV64257888; called by muse, mutect2, varscan2
- PREX2 | c.3446G>A p.R1149H | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as rs748595305, COSV55802043; called by muse, mutect2, varscan2
- PRG3 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV54663248; called by muse, mutect2, varscan2
- PRICKLE3 | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as COSV100889896; called by muse, mutect2, varscan2
- PRKACB | c.591G>T p.W197C | Missense Mutation (SNP) | VAF 134/443 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs950096058, COSV65758998; called by muse, mutect2, varscan2
- PRKN | c.665C>A p.T222K | Missense Mutation (SNP) | VAF 308/1018 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs1206205875, COSV100627893; called by muse, mutect2, varscan2
- PSMD1 | c.2191A>G p.I731V | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as rs189389369, COSV100433405; called by muse, mutect2, varscan2
- PTGES2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99476259; called by muse, mutect2, varscan2
- PTK2B | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 225/997 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.024); catalogued as COSV57750997; called by muse, mutect2, varscan2
- PTK2B | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57751024; called by muse, mutect2, varscan2
- PTPN4 | c.1355+1G>A p.X452_splice | Splice Site (SNP) | VAF 111/376 reads (30%) | catalogued as rs147418905, COSV55298307; called by muse, mutect2, varscan2
- PTPRK | c.3706G>T p.D1236Y (on ENST00000368215 / NM_001291984.2; = p.D1237Y on NM_002844.4) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100950500; called by muse, mutect2, varscan2
- PTPRS | c.3959G>A p.R1320H | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as rs936142250, COSV53614631, COSV53625171; called by muse, mutect2, varscan2
- PWWP3B | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100531007; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3637T>C p.Y1213H (on ENST00000330843 / NM_001002814.3; = p.Y579H on NM_025151.5) | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as COSV99769788; called by muse, mutect2, varscan2
- RAB40C | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV50192957; called by muse, mutect2, varscan2
- RAD51C | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 102/274 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV100506883; called by muse, mutect2, varscan2
- RAD9B | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 184/499 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV62194462; called by muse, mutect2, varscan2
- RASA1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 116/374 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1305400293, COSV57198473; called by muse, mutect2, varscan2
- RBM26 | c.288A>T p.E96D | Missense Mutation (SNP) | VAF 227/609 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99935895; called by muse, mutect2, varscan2
- RBM33 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201031900, COSV56629648; called by muse, mutect2, varscan2
- RBPJ | c.674-1G>A p.X225_splice | Splice Site (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100623544; called by muse, mutect2, varscan2
- RBPJL | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775667917, COSV100636921; called by muse, mutect2, varscan2
- RBSN | c.2320C>T p.H774Y | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as COSV99515085; called by muse, mutect2, varscan2
- REM2 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99944582, COSV99944798; called by muse, mutect2, varscan2
- REST | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs958664617, COSV100470745; called by muse, mutect2, varscan2
- RET | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); catalogued as rs570176656, COSV60688178, COSV60694580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX5 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as rs766158684, COSV51839942; called by muse, mutect2, varscan2
- RGS20 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs141996990; called by muse, varscan2
- RHAG | c.22A>G p.M8V | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1434904710, COSV57706881; called by muse, mutect2, varscan2
- RIF1 | c.4654T>G p.S1552A | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.2); catalogued as COSV99690222; called by muse, mutect2, varscan2
- RINT1 | c.740del p.P247Lfs*8 | Frame Shift Del (DEL) | VAF 40/274 reads (15%) | catalogued as rs1352349454; called by mutect2, pindel, varscan2
- RIOK1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs769061872, COSV53573875; called by muse, mutect2, varscan2
- RIT2 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 48/132 reads (36%) | catalogued as rs1359368764, COSV56295691, COSV56296873; called by muse, varscan2
- RNF10 | c.1981A>G p.T661A | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as COSV100378505; called by muse, varscan2
- RNF111 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs762937096, COSV62085121; called by muse, mutect2, varscan2
- RNF112 | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV101465391; called by muse, mutect2, varscan2
- ROBO2 | c.1474A>C p.S492R | Missense Mutation (SNP) | VAF 137/491 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59899892, COSV59950939; called by muse, mutect2, varscan2
- ROBO2 | c.3254C>T p.T1085M | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as rs201486215, COSV59899898; called by muse, mutect2, varscan2
- ROR2 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs762871988, COSV65221777; called by muse, mutect2, varscan2
- RPS5 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as COSV99544822; called by muse, mutect2, varscan2
- RPTOR | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs143802144; called by muse, mutect2, varscan2
- RRN3 | c.90-1G>T p.X30_splice | Splice Site (SNP) | VAF 56/177 reads (32%) | catalogued as COSV52213473; called by muse, mutect2, varscan2
- RRNAD1 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as rs772426850, COSV100836890; called by muse, mutect2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 70/291 reads (24%) | catalogued as rs771992011; called by mutect2, varscan2
- RTL8A | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66188468; called by muse, mutect2
- RXFP2 | c.546del p.F182Lfs*30 | Frame Shift Del (DEL) | VAF 308/1246 reads (25%) | catalogued as COSV53641074; called by mutect2, pindel, varscan2
- RYR1 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 480/1623 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472590403, COSV100614900; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.5998C>A p.H2000N | Missense Mutation (SNP) | VAF 118/461 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100768649; called by muse, mutect2, varscan2
- SACS | c.3895G>T p.D1299Y | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV101207236; called by muse, mutect2, varscan2
- SART3 | c.2278C>T p.R760C (on ENST00000228284; = p.R742C on NM_014706.4) | Missense Mutation (SNP) | VAF 125/402 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs780342985, COSV57205769; called by muse, mutect2, varscan2
- SASH1 | c.3520G>A p.V1174I | Missense Mutation (SNP) | VAF 81/251 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.058); catalogued as rs577978226, COSV66562302; called by muse, mutect2, varscan2
- SATB1 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV58667840; called by muse, mutect2, varscan2
- SATL1 | c.583T>C p.W195R (on ENST00000395409; = p.W382R on NM_001012980.2) | Missense Mutation (SNP) | VAF 134/633 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1340098396; called by muse, varscan2
- SBK1 | c.706del p.V236Cfs*121 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as COSV59396178, COSV59396832; called by mutect2, varscan2
- SCN5A | c.1412G>T p.S471I | Missense Mutation (SNP) | VAF 237/610 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV100346906; called by muse, mutect2, varscan2
- SCN9A | c.1289T>C p.L430P | Missense Mutation (SNP) | VAF 43/818 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100311782; called by muse, mutect2
- SCPEP1 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs769859901, COSV99227721; called by muse, mutect2, varscan2
- SCUBE2 | c.2758G>A p.A920T (on ENST00000649792 / NM_001367977.2; = p.A863T on NM_020974.3) | Missense Mutation (SNP) | VAF 87/270 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138426692, COSV58542196; called by muse, mutect2, varscan2
- SCYL3 | c.52T>C p.F18L | Missense Mutation (SNP) | VAF 407/1311 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100884267; called by muse, mutect2, varscan2
- SEC13 | c.800A>G p.H267R (on ENST00000350697 / NM_183352.3; = p.H270R on NM_030673.4) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as rs754797935, COSV100491271; called by muse, mutect2, varscan2
- SEC63 | c.1209+2T>C p.X403_splice | Splice Site (SNP) | VAF 50/189 reads (26%) | catalogued as COSV100938325; called by muse, mutect2, varscan2
- SEL1L | c.1232A>G p.H411R | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.647); catalogued as COSV100377735; called by muse, mutect2, varscan2
- SELENOV | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV100112608; called by muse, mutect2, varscan2
- SEMA5A | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs771230983, COSV101227354; called by muse, varscan2
- SEMA5A | c.1272A>C p.T424= | Splice Region (SNP) | VAF 36/381 reads (9%) | catalogued as COSV101227356; called by muse, mutect2
- SEMG2 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.41); PolyPhen probably damaging (1); catalogued as rs749870633, COSV65647256; called by muse, mutect2, varscan2
- SERPINA10 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 97/342 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs768758518, COSV56227556; called by muse, mutect2, varscan2
- SERPINA11 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs776283166, COSV58241296; called by muse, mutect2, varscan2
- SERTAD3 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100475023; called by muse, mutect2, varscan2
- SETMAR | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV100740839; called by muse, varscan2
- SETX | c.7200A>G p.G2400= | Splice Region (SNP) | VAF 85/229 reads (37%) | catalogued as rs767939556, COSV99809000; called by muse, mutect2, varscan2
- SGIP1 | c.37T>C p.F13L | Missense Mutation (SNP) | VAF 82/1918 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); catalogued as COSV52763963; called by muse, mutect2
- SGPP1 | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99905738, COSV99905850; called by muse, mutect2, varscan2
- SH3BP4 | c.1123A>C p.S375R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100749043; called by mutect2, varscan2
- SH3GL3 | c.742T>C p.S248P | Missense Mutation (SNP) | VAF 145/485 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100196133, COSV100196194; called by muse, mutect2, varscan2
- SHANK3 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs755385740, COSV99436440; called by muse, mutect2, varscan2
- SHROOM2 | c.4399G>A p.V1467M | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as rs752261216, COSV101098263; called by muse, mutect2, varscan2
- SIGLEC5 | c.301T>C p.C101R | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570741509, COSV99707219; called by mutect2, varscan2
- SIMC1 | c.2255C>T p.S752L (on ENST00000443967 / NM_001308196.1; = p.S337L on NM_198567.5) | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.646); catalogued as rs774139061, COSV57900654; called by muse, mutect2, varscan2
- SIPA1L2 | c.1271T>G p.I424S | Missense Mutation (SNP) | VAF 134/422 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99477435; called by muse, mutect2, varscan2
- SIRPA | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV61537044; called by mutect2, varscan2
- SLC13A2 | c.1591C>A p.L531I | Missense Mutation (SNP) | VAF 88/308 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV100120175; called by muse, mutect2, varscan2
- SLC17A6 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV99580955; called by muse, mutect2, varscan2
- SLC18A1 | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV99368352; called by muse, mutect2, varscan2
- SLC1A1 | c.1508A>G p.Y503C | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as COSV99261585; called by muse, mutect2
- SLC1A7 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101019434; called by muse, mutect2, varscan2
- SLC24A4 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 248/730 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs750450461, COSV54121346; called by muse, mutect2, varscan2
- SLC27A1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs771094007, COSV99393064; called by muse, mutect2, varscan2
- SLC36A1 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 246/637 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99695418; called by muse, mutect2, varscan2
- SLC38A9 | c.1113del p.F371Lfs*10 | Frame Shift Del (DEL) | VAF 69/236 reads (29%) | catalogued as rs746769804; called by mutect2, pindel, varscan2
- SLC50A1 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 100/389 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1371253094, COSV100310239; called by muse, mutect2, varscan2
- SLC6A2 | c.1799T>C p.L600P | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); catalogued as COSV99573456; called by muse, mutect2, varscan2
- SMAD3 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs758823376, COSV59285865; called by muse, mutect2, varscan2
- SMARCA4 | c.2059A>G p.K687E | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs751565055, COSV60802258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCAD1 | c.1040del p.N347Mfs*24 | Frame Shift Del (DEL) | VAF 55/144 reads (38%) | catalogued as rs754697669; called by mutect2, varscan2
- SMARCAD1 | c.2179-2A>G p.X727_splice | Splice Site (SNP) | VAF 86/276 reads (31%) | catalogued as COSV62773568; called by muse, mutect2, varscan2
- SMC4 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100424504; called by muse, mutect2, varscan2
- SMC4 | c.2434C>T p.R812* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as rs960920466, COSV61006337; called by muse, mutect2, varscan2
- SMPD4 | c.2123C>T p.T708M (on ENST00000409031 / NM_017951.4; = p.T679M on NM_017751.4) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs201893351, COSV100302237; called by muse, mutect2, varscan2
- SNX11 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 170/605 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100821716; called by muse, mutect2, varscan2
- SNX13 | c.2585C>T p.T862I | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101296806; called by muse, mutect2, varscan2
- SNX14 | c.1084G>A p.V362M (on ENST00000314673 / NM_001350535.1; = p.V318M on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765837232, COSV100121442; called by muse, mutect2, varscan2
- SORCS2 | c.1181C>G p.T394R | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100211807, COSV61180215; called by muse, mutect2, varscan2
- SORCS2 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764411472, COSV100211810, COSV61178299; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SP1 | c.758T>C p.V253A (on ENST00000327443 / NM_138473.3; = p.V246A on NM_003109.1) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV59401965; called by muse, mutect2, varscan2
- SPAG17 | c.5118A>C p.E1706D | Missense Mutation (SNP) | VAF 348/1233 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV100308251; called by mutect2, varscan2
- SPAG5 | c.689A>G p.E230G | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as rs764245880, COSV100410489; called by muse, mutect2, varscan2
- SPART | c.1064G>T p.R355I | Missense Mutation (SNP) | VAF 265/794 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100768599, COSV62084392; called by muse, mutect2, varscan2
- SPATA31E1 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV100350042, COSV57795248; called by muse, mutect2, varscan2
- SPINDOC | c.1080G>A p.W360* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV99588461; called by muse, mutect2, varscan2
- SRFBP1 | c.707dup p.N236Kfs*5 | Frame Shift Ins (INS) | VAF 44/124 reads (35%) | catalogued as rs751748506; called by mutect2, varscan2
- SSBP3 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs368799292; called by muse, mutect2, varscan2
- SSH2 | c.2397del p.K799Nfs*18 | Frame Shift Del (DEL) | VAF 230/825 reads (28%) | catalogued as COSV52175725; called by mutect2, pindel, varscan2
- ST6GALNAC1 | c.1275G>T p.L425F | Missense Mutation (SNP) | VAF 70/199 reads (35%) | PolyPhen benign (0.249); catalogued as COSV99336286; called by muse, mutect2, varscan2
- STAM | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 111/339 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV101097994; called by muse, mutect2, varscan2
- STK33 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs550787324, COSV100173756; called by muse, mutect2, varscan2
- STRA6 | c.1257T>G p.C419W | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100120878; called by muse, mutect2, varscan2
- STRA6 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100120879, COSV60587746; called by muse, mutect2, varscan2
- STRADA | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1364545757, COSV99834947; called by muse, mutect2, varscan2
- STT3A | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 184/603 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs576205252, COSV67065293; called by muse, varscan2
- STX7 | c.87T>C p.S29= | Splice Region (SNP) | VAF 101/286 reads (35%) | catalogued as COSV100908402; called by muse, mutect2, varscan2
- SVOPL | c.976dup p.D326Gfs*18 (on ENST00000419765; = p.D174Gfs*18 on NM_174959.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 29/95 reads (31%) | catalogued as rs769304357; called by mutect2, varscan2
- SYCP2L | c.2305A>G p.S769G | Missense Mutation (SNP) | VAF 564/1487 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99304795; called by muse, mutect2, varscan2
- SYNE2 | c.2410T>A p.F804I | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100646974; called by muse, mutect2, varscan2
- SYTL2 | c.2153T>C p.I718T (on ENST00000528231 / NM_001162951.2; = p.I694T on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 368/1257 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100313774; called by muse, mutect2, varscan2
- SZT2 | c.2648T>C p.F883S | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.997); catalogued as COSV100986965; called by muse, mutect2, varscan2
- TAAR9 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 232/573 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs199962808, COSV71512249; called by muse, mutect2, varscan2
- TAPBPL | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); catalogued as rs1483036676, COSV99869007; called by muse, mutect2, varscan2
- TAS2R42 | c.745del p.S249Pfs*18 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs753101364; called by mutect2, varscan2
- TCF20 | c.4558A>C p.T1520P | Missense Mutation (SNP) | VAF 188/551 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.17); catalogued as COSV100166353; called by muse, mutect2, varscan2
- TCHH | c.4447C>T p.R1483C | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as rs765371735, COSV100914921; called by muse, mutect2, varscan2
- TECTA | c.2722A>G p.S908G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV99878989; called by muse, mutect2, varscan2
- TEP1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 174/461 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV99401828; called by muse, mutect2, varscan2
- TEPP | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs548983927, COSV52042705; called by muse, mutect2, varscan2
- TEX13B | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.302); catalogued as COSV100258268; called by muse, mutect2, varscan2
- TFAP2D | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 133/463 reads (29%) | catalogued as COSV99145725; called by muse, mutect2, varscan2
- THBS2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV100827689; called by muse, varscan2
- TLE1 | c.234+2T>C p.X78_splice | Splice Site (SNP) | VAF 41/123 reads (33%) | catalogued as COSV64685653; called by muse, mutect2, varscan2
- TMCC2 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200823989, COSV58001658; called by muse, mutect2, varscan2
- TMEM131L | c.3224T>C p.M1075T | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1326258171, COSV99546970; called by muse, mutect2, varscan2
- TMEM31 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 629/1794 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.022); catalogued as rs777080486, COSV100128986; called by muse, mutect2, varscan2
- TMEM98 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 128/458 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55582343; called by muse, mutect2, varscan2
- TMPO | c.1289C>A p.P430H | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV99701913, COSV99702257; called by muse, mutect2, varscan2
- TMX2 | c.549-2A>G p.X183_splice | Splice Site (SNP) | VAF 117/359 reads (33%) | catalogued as COSV99559818; called by muse, mutect2, varscan2
- TNK2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747816316, COSV57366452; called by muse, mutect2, varscan2
- TNPO2 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63509251; called by muse, mutect2
- TNRC6C | c.1844del p.N615Mfs*45 | Frame Shift Del (DEL) | VAF 61/141 reads (43%) | catalogued as rs867658870, COSV56951956; called by mutect2, varscan2
- TNS3 | c.1447C>A p.P483T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV100235017; called by muse, mutect2, varscan2
- TOP3A | c.2497C>T p.R833W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374011155; called by muse, mutect2, varscan2
- TOPORS | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV62116319; called by muse, mutect2, varscan2
- TP53BP2 | c.1511T>C p.V504A (on ENST00000343537 / NM_001031685.3; = p.V375A on NM_005426.2) | Missense Mutation (SNP) | VAF 155/463 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as COSV59066830; called by muse, mutect2, varscan2
- TPBG | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV63882330; called by muse, mutect2, varscan2
- TRAF5 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as rs760636610, COSV54822770, COSV99807704; called by muse, varscan2
- TRAM1L1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV100162042; called by muse, mutect2, varscan2
- TRANK1 | c.4484G>A p.R1495H | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as rs377574608; called by muse, mutect2, varscan2
- TRAPPC8 | c.3735+2T>C p.X1245_splice | Splice Site (SNP) | VAF 102/290 reads (35%) | catalogued as COSV99350678; called by muse, mutect2, varscan2
- TRIM37 | c.568A>C p.I190L | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV99232431; called by muse, mutect2, varscan2
- TRIP4 | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV99974394; called by muse, mutect2, varscan2
- TRMT1L | c.700A>T p.T234S | Missense Mutation (SNP) | VAF 187/663 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV100834573; called by muse, mutect2, varscan2
- TRPC5 | c.2777T>G p.L926R | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99459735; called by muse, mutect2, varscan2
- TSPYL1 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.095); catalogued as rs537676463, COSV63993961; called by muse, mutect2, varscan2
- TTC3 | c.3388A>G p.M1130V | Missense Mutation (SNP) | VAF 161/405 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs112814928, COSV100695173; called by muse, mutect2, varscan2
- TTLL13P | c.149del p.N50Mfs*17 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | catalogued as rs773117671; called by mutect2, pindel, varscan2
- TTN | c.2157G>C p.E719D (on ENST00000591111; = p.E673D on NM_003319.4) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | PolyPhen benign (0.291); catalogued as COSV100598995; called by muse, mutect2, varscan2
- TUT4 | c.3740T>C p.M1247T | Missense Mutation (SNP) | VAF 236/695 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99931935; called by muse, mutect2, varscan2
- TXNRD2 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs1410697719, COSV68692601; called by muse, mutect2
- UBE2O | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1241579539, COSV60064046; called by muse, mutect2, varscan2
- UGCG | c.1094del p.L365Cfs*9 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs1243652090; called by mutect2, pindel, varscan2
- UGP2 | c.1406dup p.N469Kfs*16 | Frame Shift Ins (INS) | VAF 91/350 reads (26%) | catalogued as rs1252687688; called by mutect2, pindel, varscan2
- UPK1B | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 128/397 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368350153; called by muse, mutect2, varscan2
- UROC1 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372570937; called by muse, mutect2, varscan2
- USH1C | c.1211-2A>G p.X404_splice | Splice Site (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99139461; called by muse, mutect2, varscan2
- USP24 | c.3745G>A p.G1249R | Missense Mutation (SNP) | VAF 215/708 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs1367194571, COSV53768978; called by muse, mutect2, varscan2
- USP28 | c.2914G>A p.V972I | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs758395585, COSV50164125; called by muse, mutect2, varscan2
- USP3 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 48/364 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV99165651; called by muse, mutect2, varscan2
- UTRN | c.4897T>C p.W1633R | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839676; called by muse, mutect2, varscan2
- UTRN | c.5033T>A p.I1678N | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100839677; called by muse, mutect2, varscan2
- VAC14 | c.1731G>T p.E577D | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as COSV99934245; called by muse, mutect2, varscan2
- VEPH1 | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100747421; called by muse, mutect2, varscan2
- VN1R4 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.331); catalogued as rs745568730, COSV100237342; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR62 | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs779070171, COSV99543293; called by muse, mutect2, varscan2
- WDR93 | c.1876A>G p.T626A | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.173); catalogued as COSV99175494; called by muse, mutect2, varscan2
- WNK1 | c.2708T>C p.V903A | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100266509; called by muse, mutect2, varscan2
- WNK1 | c.5906A>G p.D1969G (on ENST00000315939 / NM_018979.4; = p.D1721G on NM_014823.3) | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV60027075; called by muse, mutect2, varscan2
- XPO1 | c.2675C>T p.T892M | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.437); catalogued as rs755621083, COSV68944662; called by muse, mutect2, varscan2
- ZBTB16 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60089900; called by muse, mutect2, varscan2
- ZBTB16 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1446868303, COSV60089907; called by muse, mutect2, varscan2
- ZBTB20 | c.1193C>T p.A398V (on ENST00000474710 / NM_001164342.2; = p.A325V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1424176117, COSV61849440; called by muse, mutect2, varscan2
- ZBTB4 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs747744082, COSV100262886; called by muse, mutect2, varscan2
- ZC3H13 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 258/677 reads (38%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99667662; called by muse, mutect2, varscan2
- ZC4H2 | c.450del p.I151Sfs*36 | Frame Shift Del (DEL) | VAF 100/353 reads (28%) | catalogued as COSV62004363; called by mutect2, pindel, varscan2
- ZDHHC2 | c.524T>G p.F175C | Missense Mutation (SNP) | VAF 110/2154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100024607; called by muse, mutect2
- ZFAT | c.2677G>A p.G893S | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.51); catalogued as COSV64735320; called by muse, mutect2, varscan2
- ZFHX4 | c.4865G>T p.R1622M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99258334; called by muse, mutect2
- ZFYVE9 | c.3647T>G p.L1216R | Missense Mutation (SNP) | VAF 234/692 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99819521; called by muse, mutect2, varscan2
- ZMAT3 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as rs147086451, COSV100265317; called by muse, mutect2, varscan2
- ZMAT4 | c.578-2A>G p.X193_splice | Splice Site (SNP) | VAF 75/678 reads (11%) | catalogued as COSV99908865; called by muse, mutect2, varscan2
- ZMYND15 | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.063); catalogued as COSV99351046; called by muse, mutect2, varscan2
- ZMYND8 | c.1951A>G p.T651A (on ENST00000311275 / NM_001363741.2; = p.T671A on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 225/866 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV99519802; called by muse, varscan2
- ZNF100 | c.1365A>C p.K455N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV59746594, COSV59749229; called by muse, mutect2, varscan2
- ZNF112 | c.238+1G>A p.X80_splice (on ENST00000337401 / NM_001083335.2; = p.X74_splice on NM_013380.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 312/764 reads (41%) | catalogued as COSV100495540; called by muse, mutect2, varscan2
- ZNF189 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 363/1267 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99407107; called by muse, mutect2, varscan2
- ZNF292 | c.6556A>G p.I2186V | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370843050; called by muse, mutect2, varscan2
- ZNF317 | c.1310T>C p.M437T | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV56108590; called by muse, mutect2, varscan2
- ZNF318 | c.4024A>G p.T1342A | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as rs1365581865, COSV100546012; called by muse, mutect2, varscan2
- ZNF382 | c.1381del p.E461Kfs*84 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as COSV53086628, COSV53090943; called by mutect2, pindel, varscan2
- ZNF419 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99691860; called by muse, mutect2, varscan2
- ZNF518A | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV100283382; called by muse, mutect2
- ZNF554 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.992); catalogued as COSV100421123; called by muse, mutect2, varscan2
- ZNF570 | c.605dup p.N202Kfs*6 | Frame Shift Ins (INS) | VAF 31/78 reads (40%) | catalogued as rs758109083; called by mutect2, varscan2
- ZNF609 | c.3299A>G p.K1100R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV100440525; called by muse, mutect2, varscan2
- ZNF638 | c.5587C>A p.P1863T | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV100038195; called by muse, mutect2, varscan2
- ZNF714 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.833); catalogued as rs1291832714, COSV52510100; called by muse, mutect2
- ZNF721 | c.2060G>A p.C687Y (on ENST00000338977; = p.C699Y on NM_133474.4) | Missense Mutation (SNP) | VAF 177/461 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100167141; called by muse, mutect2, varscan2
- ADAD1 | c.1581dup p.E528Rfs*4 | Frame Shift Ins (INS) | VAF 128/413 reads (31%) | called by mutect2, varscan2
- ADGRF4 | c.1940del p.F647Sfs*13 | Frame Shift Del (DEL) | VAF 48/180 reads (27%) | called by pindel, varscan2
- AGGF1 | c.2042del p.N681Tfs*29 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, varscan2
- AKAP6 | c.3104T>C p.L1035P | Missense Mutation (SNP) | VAF 28/1002 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); called by muse, mutect2
- ALDH7A1 | c.586T>C p.F196L | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ANKRD12 | c.5536del p.I1846* | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | called by mutect2, pindel, varscan2
- ANKRD39 | c.290del p.G97Vfs*35 | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | called by pindel, varscan2
- AP3M2 | c.952del p.V318Sfs*2 | Frame Shift Del (DEL) | VAF 47/153 reads (31%) | called by mutect2, pindel, varscan2
- ARID4A | c.1958del p.K653Rfs*19 | Frame Shift Del (DEL) | VAF 33/121 reads (27%) | called by mutect2, pindel, varscan2
- ATP10D | c.2588dup p.L863Ffs*3 | Frame Shift Ins (INS) | VAF 104/410 reads (25%) | called by mutect2, pindel, varscan2
- ATP2A2 | c.2996A>G p.Q999R | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRX | c.2978del p.K993Rfs*10 | Frame Shift Del (DEL) | VAF 46/184 reads (25%) | called by mutect2, varscan2
- AVPR1B | c.418del p.L140Cfs*38 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- BCL9 | c.3415del p.Q1139Rfs*138 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- BEST4 | c.101dup p.E35Gfs*13 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | called by pindel, varscan2
- C11orf24 | c.1100dup p.T368Hfs*2 | Frame Shift Ins (INS) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- C5orf34 | c.50T>A p.V17E | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D3 | c.663del p.F221Lfs*40 | Frame Shift Del (DEL) | VAF 212/604 reads (35%) | called by mutect2, varscan2
- CAMK2D | c.1363_1364dup p.W455Cfs*49 | Frame Shift Ins (INS) | VAF 157/426 reads (37%) | called by mutect2, varscan2
- CCDC178 | c.1993del p.Y665Mfs*4 (on ENST00000383096 / NM_001105528.3; = p.Y627Mfs*4 on NM_198995.3) | Frame Shift Del (DEL) | VAF 49/383 reads (13%) | called by mutect2, pindel, varscan2
- CENPF | c.442del p.I148Ffs*6 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | called by pindel, varscan2
- CLMP | c.891del p.R298Afs*38 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | called by mutect2, pindel, varscan2
- CNGB3 | c.2417del p.K806Rfs*23 | Frame Shift Del (DEL) | VAF 242/847 reads (29%) | called by mutect2, pindel, varscan2
- COPS7A | c.655del p.T219Pfs*21 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, varscan2
- CROT | c.232dup p.R78Kfs*34 | Frame Shift Ins (INS) | VAF 54/198 reads (27%) | called by mutect2, pindel, varscan2
- CRYBB1 | c.76dup p.A26Gfs*9 | Frame Shift Ins (INS) | VAF 52/231 reads (23%) | called by mutect2, pindel, varscan2
- CYLD | c.1725_1727del p.P577del | In Frame Del (DEL) | VAF 32/115 reads (28%) | called by pindel, varscan2
- DCLK2 | c.780dup p.G261Wfs*2 | Frame Shift Ins (INS) | VAF 818/2413 reads (34%) | called by mutect2, varscan2
- DISP1 | c.4408dup p.E1470Gfs*5 | Frame Shift Ins (INS) | VAF 42/166 reads (25%) | called by mutect2, pindel, varscan2
- DLG2 | c.2488T>A p.F830I | Missense Mutation (SNP) | VAF 59/1540 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DLGAP3 | c.1130del p.G377Vfs*91 | Frame Shift Del (DEL) | VAF 70/257 reads (27%) | called by mutect2, pindel, varscan2
- DNAJA3 | c.1133del p.P378Lfs*39 | Frame Shift Del (DEL) | VAF 38/165 reads (23%) | called by mutect2, pindel, varscan2
- EGLN2 | c.192del p.R65Efs*86 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- EIF2AK4 | c.1436_1438del p.G479del | In Frame Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- EXOC2 | c.25del p.V10* | Frame Shift Del (DEL) | VAF 158/413 reads (38%) | called by mutect2, pindel, varscan2
- EYA4 | c.83+2T>C p.X28_splice | Splice Site (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- GPR171 | c.64del p.Y22Ifs*2 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by mutect2, varscan2
- GPR37L1 | c.82dup p.L28Pfs*24 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- GRM6 | c.929dup p.A311Sfs*30 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by mutect2, varscan2
- HDAC7 | c.2153_2155del p.F718del (on ENST00000427332; = p.F757del on NM_015401.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 85/247 reads (34%) | called by mutect2, pindel, varscan2
- HOOK2 | c.1870del p.A624Hfs*8 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- IGF2 | c.677del p.G226Afs*30 (on ENST00000434045 / NM_001127598.3; = p.G170Afs*30 on NM_000612.6) | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- IGHV1-58 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2
- IGHV1OR21-1 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- IGLV1-50 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGLV7-46 | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IL31RA | c.347dup p.L117Pfs*9 | Frame Shift Ins (INS) | VAF 121/472 reads (26%) | called by mutect2, pindel, varscan2
- INTS2 | c.3300del p.F1100Lfs*26 | Frame Shift Del (DEL) | VAF 46/166 reads (28%) | called by mutect2, pindel, varscan2
- KIAA0930 | c.876dup p.T293Hfs*26 (on ENST00000336156 / NM_001009880.2; = p.T298Hfs*26 on NM_015264.2) | Frame Shift Ins (INS) | VAF 33/139 reads (24%) | called by mutect2, pindel, varscan2
- KLC1 | c.468del p.K156Nfs*65 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- KLRD1 | c.241dup p.T81Nfs*24 | Frame Shift Ins (INS) | VAF 98/340 reads (29%) | called by mutect2, pindel, varscan2
- LARP4B | c.486_487del p.K162Nfs*8 | Frame Shift Del (DEL) | VAF 324/995 reads (33%) | called by pindel, varscan2
- LINGO2 | c.1813del p.M605* | Frame Shift Del (DEL) | VAF 55/223 reads (25%) | called by mutect2, pindel, varscan2
- LRP1 | c.4468del p.E1490Rfs*80 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- LRRK2 | c.6782dup p.N2261Kfs*9 | Frame Shift Ins (INS) | VAF 65/242 reads (27%) | called by mutect2, varscan2
- LSR | c.1228_1230del p.K410del (on ENST00000361790; = p.K391del on NM_015925.6) | In Frame Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- MAML1 | c.481del p.L161Sfs*23 | Frame Shift Del (DEL) | VAF 57/220 reads (26%) | called by mutect2, pindel, varscan2
- MAPKBP1 | c.503dup p.N168Kfs*20 | Frame Shift Ins (INS) | VAF 57/183 reads (31%) | called by mutect2, pindel, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 44/63 reads (70%) | called by mutect2, varscan2
- MEI1 | c.672del p.L226Sfs*22 | Frame Shift Del (DEL) | VAF 82/356 reads (23%) | called by mutect2, pindel, varscan2
- MYORG | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 101/291 reads (35%) | called by mutect2, pindel, varscan2
299 further variants in this file (58 protein-altering or splice-affecting, 227 silent, 14 other) are not listed here.
